Somatic mutation profile of tumor specimen TCGA-HZ-A4BK-01A (aliquot TCGA-HZ-A4BK-01A-11D-A26I-08) from TCGA case TCGA-HZ-A4BK, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.6 years (26,503 days).
Specimen TCGA-HZ-A4BK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 884dd8cd-185f-4756-aac2-4adc4e673149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A4BK-10A (Blood Derived Normal), aliquot TCGA-HZ-A4BK-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b9d1e93-f9b6-4e17-963c-a098a573d8d7

The open-access MAF lists 53 somatic variants for this specimen: 45 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 42, Silent 8, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEST1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs886041141, CM111671, COSV100077295; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 41/131 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs730880870, CM066922, COSV62518906; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 51/285 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2158G>A p.G720S | Missense Mutation (SNP) | VAF 74/1012 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs542184069, COSV53988449; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTS12 | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 54/624 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs777630888, COSV100711434, COSV61275688; called by muse, mutect2
- ASB15 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 92/1078 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99306839; called by muse, mutect2
- BMPR1A | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 48/634 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs567009904, COSV100923663, COSV64409673; ClinVar: uncertain significance; called by muse, mutect2
- CHST4 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1001345250, COSV100632908; called by muse, mutect2
- COL11A1 | c.2456C>G p.A819G | Missense Mutation (SNP) | VAF 30/419 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs749913678, COSV100617643, COSV62175388, COSV62200611; called by muse, mutect2
- CSMD3 | c.2281C>T p.L761F (on ENST00000297405 / NM_001363185.1; = p.L657F on NM_052900.3) | Missense Mutation (SNP) | VAF 44/594 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52129362, COSV99828094, COSV99841759; called by muse, mutect2
- DCHS1 | c.4957G>C p.E1653Q | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV100202357; called by muse, mutect2, varscan2
- DISP3 | c.3745G>A p.V1249M | Missense Mutation (SNP) | VAF 35/458 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53823647; called by muse, mutect2
- DSCAML1 | c.4850C>T p.A1617V (on ENST00000321322; = p.A1557V on NM_020693.4) | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58398476; called by muse, mutect2
- DYSF | c.5576G>A p.R1859H | Missense Mutation (SNP) | VAF 47/566 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs143939123; called by muse, mutect2
- F5 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 80/539 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV100889190; called by muse, mutect2, varscan2
- FAT2 | c.10034C>T p.A3345V | Missense Mutation (SNP) | VAF 98/548 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1203648027, COSV55827475; called by muse, mutect2, varscan2
- FLT4 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 109/583 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs1185976621, COSV56112565; called by muse, mutect2, varscan2
- GFER | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 38/512 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99937085; called by muse, mutect2
- GNL3 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV99803985; called by muse, mutect2
- GNL3 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99803988; called by muse, mutect2
- GPM6B | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100366411; called by muse, mutect2, varscan2
- INTS11 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 212/1118 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs764130667, COSV60088963; called by muse, mutect2, varscan2
- KCNB2 | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 50/514 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101578887; called by muse, mutect2
- LTN1 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 56/700 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100798092; called by muse, mutect2
- MFAP3L | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 48/455 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100852695; called by muse, mutect2, varscan2
- MKX | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 64/763 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs1402490120, COSV101008839; called by muse, mutect2
- OR52D1 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 26/426 reads (6%) | catalogued as COSV100495277, COSV59486893; called by muse, mutect2
- P4HA1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 51/694 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99697061; called by muse, mutect2
- PACSIN1 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as COSV99763244; called by muse, mutect2
- PAPSS2 | c.27+2T>C p.X9_splice | Splice Site (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100630787; called by muse, mutect2
- PCDHB3 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 48/740 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1554272567, COSV50619820; called by muse, mutect2
- PI4KB | c.821G>A p.R274H (on ENST00000368873 / NM_001369623.1; = p.R286H on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/447 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761617123, COSV55021204; called by muse, mutect2
- PKN1 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99466564; called by muse, mutect2
- POM121L12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200929126, COSV68692625; called by muse, mutect2, varscan2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 172/2345 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2
- RORC | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs546157871, COSV100561999, COSV59091834; called by muse, mutect2
- RYR2 | c.1694T>C p.L565P | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV100772043; called by muse, mutect2, varscan2
- SEMA5B | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778251817, COSV52095129, COSV99533431; called by muse, mutect2
- SLCO5A1 | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.261); catalogued as rs141622109; called by muse, mutect2, varscan2
- STS | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99481515; called by muse, mutect2
- TARS1 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99466256; called by muse, mutect2
- ZNF141 | c.986A>G p.H329R | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782029537, COSV99549893; called by muse, mutect2, varscan2
- ZNF681 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 17/300 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101267532; called by muse, mutect2
- AGAP6 | c.1566del p.S524Afs*69 (on ENST00000374056 / NM_001365867.1; = p.S547Afs*69 on NM_001077665.2) | Frame Shift Del (DEL) | VAF 107/792 reads (14%) | called by mutect2, varscan2
- CCDC7 | c.42G>A p.S14= | Silent (SNP) | VAF 58/369 reads (16%) | catalogued as rs1008424258, COSV99511767; called by muse, mutect2, varscan2
- DHX8 | c.162C>T p.I54= | Silent (SNP) | VAF 57/513 reads (11%) | catalogued as COSV99292474; called by muse, varscan2
- KRT37 | c.1080C>G p.A360= | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as COSV99845637; called by muse, mutect2, varscan2
- PLEKHM1 | c.1659C>G p.L553= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV101378824; called by muse, mutect2, varscan2
- RIMBP2 | c.396C>T p.S132= | Silent (SNP) | VAF 73/405 reads (18%) | catalogued as rs773151382, COSV55476405; called by muse, mutect2, varscan2
- SRPK3 | c.507C>T p.H169= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as COSV54206116, COSV99473318; called by muse, mutect2
- ZIC3 | c.636C>T p.A212= | Silent (SNP) | VAF 23/235 reads (10%) | catalogued as COSV54976094, COSV99798660; called by muse, mutect2
- ZSWIM4 | c.648G>A p.L216= | Silent (SNP) | VAF 39/233 reads (17%) | catalogued as rs1409232003, COSV99585167; called by muse, mutect2, varscan2
